Somatic mutation profile of tumor specimen C3N-00519-02 (aliquot CPT0013430009) from CPTAC case C3N-00519, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 67.2 years (24,556 days).
Specimen C3N-00519-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 402d6a18-2b44-453e-9ce8-57a74e20fc18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00519-31 (Blood Derived Normal), aliquot CPT0013520002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/587734fc-b27d-40e0-ade3-7ccb6bcbc64b

The open-access MAF lists 242 somatic variants for this specimen: 172 protein-altering or splice-affecting, 49 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 49, Nonsense Mutation 17, Intron 10, Splice Region 4, 5'Flank 3, 5'UTR 3, 3'UTR 2, Frame Shift Ins 2, RNA 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTB | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs886041309, COSV59317066, COSV59317805; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 42/330 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AATK | c.3667G>A p.E1223K (on ENST00000326724 / NM_001080395.3; = p.E1120K on NM_004920.2) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs1368384033; called by muse, mutect2, varscan2
- ADCY7 | c.3093C>G p.I1031M | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54267046; called by muse, mutect2
- APOB | c.3080G>C p.R1027T | Missense Mutation (SNP) | VAF 36/461 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs147896704; called by muse, mutect2
- ARMC6 | c.187G>C p.E63Q (on ENST00000392336; = p.E38Q on NM_033415.4) | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV99523142; called by muse, mutect2
- C2CD2L | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100371087; called by muse, mutect2
- CASP8 | c.1363G>C p.D455H (on ENST00000432109 / NM_033355.3; = p.D472H on NM_001228.4) | Missense Mutation (SNP) | VAF 10/351 reads (3%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.873); catalogued as COSV51861501; called by muse, mutect2
- CASS4 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV64388571; called by muse, mutect2, varscan2
- CNOT9 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55302090; called by muse, varscan2
- COBL | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 19/406 reads (5%) | catalogued as COSV104371568; called by muse, mutect2
- CPN1 | c.1183G>C p.D395H | Missense Mutation (SNP) | VAF 16/500 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV64941865; called by muse, mutect2
- CTTN | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57232589; called by muse, mutect2
- EEPD1 | c.1695C>G p.I565M | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV54195469; called by muse, mutect2
- ELAPOR2 | c.456C>G p.F152L | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.089); catalogued as rs994223189; called by muse, mutect2
- ENPEP | c.2305G>C p.E769Q | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV99488115; called by muse, mutect2
- EPM2AIP1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV99212667; called by muse, mutect2
- FNDC1 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV51930106; called by muse, mutect2, varscan2
- GABRD | c.498G>T p.M166I | Missense Mutation (SNP) | VAF 24/622 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as CX158799; called by muse, mutect2
- GABRG2 | c.764G>C p.R255P (on ENST00000361925 / NM_001375343.1; = p.R215P on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/401 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs1561645172, COSV62715550; ClinVar: uncertain significance; called by muse, mutect2
- GABRG3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as COSV61520594, COSV61521127; called by muse, mutect2
- GLP2R | c.705C>G p.F235L | Missense Mutation (SNP) | VAF 12/275 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99301827; called by muse, mutect2
- GPR75 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 11/257 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61827149; called by muse, mutect2
- HMCN1 | c.13296G>A p.M4432I | Missense Mutation (SNP) | VAF 66/458 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV54928555, COSV99630319; called by muse, mutect2, varscan2
- IGLV2-18 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 25/501 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1320895829; called by muse, mutect2
- INPP4B | c.2361G>C p.K787N | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.681); catalogued as COSV99527292; called by muse, mutect2
- ITGA10 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs782794751, COSV65197987; called by muse, mutect2, varscan2
- JAG2 | c.1993G>A p.G665S | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs768425653; called by muse, mutect2
- KDF1 | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1312899616; called by muse, mutect2
- LATS2 | c.1767G>C p.K589N | Missense Mutation (SNP) | VAF 12/402 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV66874614; called by muse, mutect2
- LRP1B | c.4519C>T p.Q1507* | Nonsense Mutation (SNP) | VAF 7/138 reads (5%) | catalogued as COSV67259285; called by muse, mutect2
- LRP5 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 15/393 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1404203617; called by muse, mutect2
- MAGEA6 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs1556826858; called by muse, mutect2, varscan2
- MUC16 | c.8491G>C p.E2831Q | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV67459539; called by muse, mutect2
- OLFM2 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1343565418, COSV53428240; called by muse, mutect2
- OR7E24 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 12/280 reads (4%) | catalogued as COSV71702327; called by muse, mutect2
- PDZRN4 | c.1799T>G p.L600R (on ENST00000402685 / NM_001164595.2; = p.L342R on NM_013377.4) | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV54196850; called by muse, mutect2
- PFKP | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs560699702, COSV66902442; called by muse, mutect2, varscan2
- PLEC | c.13804G>C p.E4602Q (on ENST00000322810 / NM_201380.4; = p.E4492Q on NM_000445.5) | Missense Mutation (SNP) | VAF 16/604 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV100518546; called by muse, mutect2
- PLEKHG6 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs895481409, COSV99164850; called by muse, mutect2
- RASAL2 | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 13/352 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV100862387; called by muse, mutect2
- RGS7 | c.786A>C p.I262= | Splice Region (SNP) | VAF 9/102 reads (9%) | catalogued as COSV58531066; called by muse, mutect2
- RNASEH2A | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 37/481 reads (8%) | catalogued as rs867179008; called by muse, mutect2
- RNF150 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV60798542; called by muse, mutect2
- RYR1 | c.7108G>T p.G2370C | Missense Mutation (SNP) | VAF 23/365 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100615819; called by muse, mutect2
- RYR3 | c.14481G>C p.L4827F (on ENST00000389232; = p.L4828F on NM_001036.6) | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV60732449; called by muse, mutect2
- SLC6A18 | c.1407G>C p.E469D | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.065); catalogued as COSV99722100; called by muse, mutect2, varscan2
- SMG1 | c.3958G>A p.V1320M | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV101245982; called by muse, mutect2
- SOX11 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58984114, COSV58986802; called by muse, mutect2
- SREBF2 | c.550C>G p.Q184E | Missense Mutation (SNP) | VAF 20/502 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.169); catalogued as COSV63332273; called by muse, mutect2
- SRRT | c.561C>G p.F187L | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV61453829, COSV61454863; called by muse, mutect2
- SSPOP | n.7655G>A | Splice Region (SNP) | VAF 16/183 reads (9%) | catalogued as rs775700429, COSV100947094; called by muse, mutect2
- TEKT4 | c.1098G>C p.L366F | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs782213190, COSV54624684; called by muse, mutect2
- TMEM253 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as rs1174170402; called by muse, mutect2
- TRPV4 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 36/533 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as rs373539744; ClinVar: uncertain significance; called by muse, mutect2
- TTLL12 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.067); catalogued as rs778703258; called by muse, mutect2
- VPS18 | c.1859G>T p.R620L | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as COSV99592384; called by muse, mutect2
- WDFY4 | c.5482G>A p.A1828T | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1214178497; called by muse, mutect2
- WNK1 | c.382A>T p.T128S | Missense Mutation (SNP) | VAF 10/269 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV60035278; called by muse, mutect2
- ZNF436 | c.1281C>G p.F427L | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58358254; called by muse, mutect2
- ZNF524 | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 18/289 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV99684401; called by muse, mutect2
- ZNF699 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV100427082; called by muse, mutect2
- AC011005.1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by muse, mutect2
- AGAP3 | c.2017dup p.A673Gfs*10 (on ENST00000622464; = p.A709Gfs*10 on NM_031946.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 30/284 reads (11%) | called by mutect2, pindel
- AHDC1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2
- ALG10 | c.23A>T p.Y8F | Missense Mutation (SNP) | VAF 17/237 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- ALS2CL | c.1487G>T p.G496V | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ANO3 | c.555G>C p.K185N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.517); called by muse, mutect2
- AOC1 | c.714C>G p.Y238* | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- AQR | c.4306G>C p.D1436H | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.094); called by muse, mutect2
- ATP6V0A2 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AZIN1 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.947); called by muse, mutect2
- BBOX1 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- C7orf31 | c.1055G>C p.R352T | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- CACNA2D2 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- CCDC105 | c.288G>A p.W96* | Nonsense Mutation (SNP) | VAF 8/155 reads (5%) | called by muse, mutect2
- CCDC39 | c.1479G>C p.E493D | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.165); called by muse, mutect2
- CENPC | c.1316C>G p.S439C | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); called by muse, mutect2
- CHD8 | c.4282G>A p.E1428K (on ENST00000646647 / NM_001170629.2; = p.E1149K on NM_020920.4) | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.277); called by muse, mutect2
- CHDH | c.1372G>C p.D458H | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CIT | c.4275C>G p.F1425L | Missense Mutation (SNP) | VAF 22/359 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CLEC1B | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- COL7A1 | c.3794G>A p.R1265K | Missense Mutation (SNP) | VAF 18/536 reads (3%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- CTTN | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2
- CTTNBP2 | c.1382A>T p.Q461L | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- DCAF10 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH2 | c.12737C>G p.S4246* | Nonsense Mutation (SNP) | VAF 9/199 reads (5%) | called by muse, mutect2
- DNPH1 | c.248G>A p.W83* | Nonsense Mutation (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.5127G>A p.M1709I | Missense Mutation (SNP) | VAF 23/320 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); called by muse, mutect2
- EIF4ENIF1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.97); PolyPhen benign (0.007); called by muse, mutect2
- ELF1 | c.1693C>G p.L565V | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- ERBB4 | c.659G>A p.R220K | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EVPL | c.4372G>C p.E1458Q | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- EVX2 | c.1337C>G p.S446C | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- FAM171A1 | c.2038C>T p.Q680* | Nonsense Mutation (SNP) | VAF 23/399 reads (6%) | called by muse, mutect2
- FAT2 | c.9685G>T p.E3229* | Nonsense Mutation (SNP) | VAF 24/316 reads (8%) | called by muse, mutect2
- GGT5 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.144); called by muse, mutect2
- GMCL1 | c.309G>C p.L103F | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- GOLGA6L2 | c.229G>C p.A77P | Missense Mutation (SNP) | VAF 9/227 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2
- HNRNPM | c.695G>C p.R232P | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HOXA2 | c.1058A>T p.D353V | Missense Mutation (SNP) | VAF 41/484 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2
- HSPA2 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- HTRA4 | c.814C>G p.R272G | Missense Mutation (SNP) | VAF 21/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ITGA2B | c.2991C>G p.I997M | Missense Mutation (SNP) | VAF 48/520 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2
- ITPR3 | c.4728C>A p.F1576L | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.079); called by muse, mutect2
- KCNK5 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2
- KCNQ1 | c.1145A>G p.Y382C | Missense Mutation (SNP) | VAF 26/498 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2
- KCTD11 | c.295G>A p.E99K (on ENST00000333751 / NM_001363642.1; = p.E60K on NM_001002914.2) | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KCTD20 | c.482A>G p.K161R | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); called by muse, mutect2
- KIAA1210 | c.4070A>G p.K1357R | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KRT31 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.262); called by muse, mutect2
- MAGEA12 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, varscan2
- MAPK8IP1 | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- NBPF15 | c.1397C>G p.S466* | Nonsense Mutation (SNP) | VAF 28/631 reads (4%) | called by muse, mutect2
- NCBP2L | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- NELL2 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2
- OR52N1 | c.700G>C p.D234H | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- OR5B21 | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); called by muse, mutect2
- PATZ1 | c.509C>G p.A170G | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2
- PDIK1L | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 11/312 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PHF3 | c.4240C>G p.Q1414E | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- POLQ | c.5690A>G p.D1897G | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PPP2CB | c.35A>G p.Q12R | Missense Mutation (SNP) | VAF 18/345 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PURB | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RABEPK | c.900C>G p.I300M | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- RAI1 | c.631C>G p.Q211E | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- RORC | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RREB1 | c.4202G>A p.S1401N | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2
- RYR2 | c.13240G>A p.E4414K | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.578); called by muse, mutect2
- SCFD2 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2
- SCYL3 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SDK2 | c.2674G>T p.E892* | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- SH3GLB2 | c.212G>C p.R71P | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SLC22A2 | c.342G>C p.R114S | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.057); called by muse, mutect2
- SLC2A1 | c.1075-6C>T | Splice Region (SNP) | VAF 13/385 reads (3%) | called by muse, mutect2
- SLC44A4 | c.628G>C p.D210H | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2
- SLC4A4 | c.319C>T p.Q107* (on ENST00000264485 / NM_001098484.3; = p.Q63* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- SLC5A9 | c.623C>A p.A208D | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SLFN12 | c.949A>G p.K317E | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.03); called by muse, mutect2
- SMU1 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- SOS1 | c.2378C>G p.S793* | Nonsense Mutation (SNP) | VAF 10/269 reads (4%) | called by muse, mutect2
- SPATC1 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ST18 | c.2442G>C p.L814= | Splice Region (SNP) | VAF 13/192 reads (7%) | called by muse, mutect2
- SVIL | c.4355G>C p.R1452T (on ENST00000355867 / NM_021738.3; = p.R1026T on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2
- TASOR | c.1000C>G p.P334A | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.079); called by muse, varscan2
- TMEM35A | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNFSF14 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- TNKS2 | c.1200C>G p.F400L | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.006); called by muse, mutect2
- TRGV5 | c.256T>G p.Y86D | Missense Mutation (SNP) | VAF 25/324 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- TRIP10 | c.344T>C p.M115T | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.108); called by muse, mutect2
- TRIT1 | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2
- TRMT10B | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2
- TRPM4 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 57/477 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- TTC19 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); called by muse, mutect2
- TTI1 | c.2056T>G p.S686A | Missense Mutation (SNP) | VAF 43/420 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- USE1 | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); called by muse, mutect2
- VCAN | c.9502dup p.T3168Nfs*3 | Frame Shift Ins (INS) | VAF 44/514 reads (9%) | called by mutect2, pindel
- VPS13A | c.9115C>G p.P3039A | Missense Mutation (SNP) | VAF 27/288 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); called by muse, mutect2
- VTN | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 19/333 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.075); called by muse, mutect2
- WDR44 | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- WRAP53 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 56/552 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.637); called by muse, mutect2
- ZHX2 | c.1138C>G p.Q380E | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0.15); called by muse, mutect2
- ZMAT3 | c.31C>G p.P11A | Missense Mutation (SNP) | VAF 16/287 reads (6%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2
- ZNF106 | c.1876G>C p.E626Q | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- ZNF148 | c.724A>G p.M242V | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF33A | c.2147G>C p.G716A (on ENST00000458705 / NM_006974.3; = p.G717A on NM_006954.2) | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.291); called by muse, mutect2
- ZNF506 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.344); called by muse, mutect2
- ZNF593 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.234); called by muse, mutect2
- ZNF707 | c.53C>G p.S18* | Nonsense Mutation (SNP) | VAF 8/193 reads (4%) | called by muse, mutect2
- ZNF804B | c.3110C>G p.S1037C | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.817); called by muse, mutect2
- ZNF821 | c.265G>C p.E89Q (on ENST00000425432 / NM_001376297.1; = p.E47Q on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.039); called by muse, mutect2
- ZSCAN23 | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.239); called by muse, mutect2
- ACADVL | c.390G>A p.E130= | Silent (SNP) | VAF 50/664 reads (8%) | called by muse, mutect2
- APOB | c.7890G>A p.Q2630= | Silent (SNP) | VAF 13/226 reads (6%) | catalogued as rs1440207007; called by muse, mutect2
- APOB | c.4938G>A p.R1646= | Silent (SNP) | VAF 8/123 reads (7%) | catalogued as COSV51930050; called by muse, mutect2
- ATG2B | c.888C>G p.L296= | Silent (SNP) | VAF 7/108 reads (6%) | catalogued as COSV63425068; called by muse, mutect2
- CAPN9 | c.219C>T p.I73= | Silent (SNP) | VAF 32/274 reads (12%) | catalogued as rs1026860903; called by muse, mutect2, varscan2
- CDH9 | c.1803C>T p.T601= | Silent (SNP) | VAF 14/434 reads (3%) | catalogued as rs934703578, COSV99142853; called by muse, mutect2
- CELSR1 | c.3735C>T p.F1245= | Silent (SNP) | VAF 14/500 reads (3%) | called by muse, mutect2
- DHX16 | c.390G>A p.K130= | Silent (SNP) | VAF 18/386 reads (5%) | called by muse, mutect2
- FARSB | c.1530C>T p.I510= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as COSV99918757; called by muse, mutect2
- FASTKD5 | c.147C>T p.L49= | Silent (SNP) | VAF 18/320 reads (6%) | called by muse, mutect2
- FGD6 | c.3078G>T p.L1026= | Silent (SNP) | VAF 13/394 reads (3%) | called by muse, mutect2
- FOXP2 | c.1338C>G p.T446= | Silent (SNP) | VAF 18/375 reads (5%) | called by muse, mutect2
- GABRR1 | c.372G>C p.L124= | Silent (SNP) | VAF 13/292 reads (4%) | called by muse, mutect2
- HIPK1 | c.300C>T p.F100= | Silent (SNP) | VAF 16/413 reads (4%) | called by muse, mutect2
- HMCN2 | c.14424C>T p.V4808= | Silent (SNP) | VAF 34/410 reads (8%) | called by muse, mutect2
- KIR2DL4 | c.336C>G p.L112= (on ENST00000396284; = p.L73= on NM_001080770.2) | Silent (SNP) | VAF 21/380 reads (6%) | called by muse, mutect2
- LHCGR | c.1569C>G p.L523= | Silent (SNP) | VAF 12/304 reads (4%) | called by muse, mutect2
- MAGEA12 | c.309G>A p.T103= | Silent (SNP) | VAF 20/171 reads (12%) | catalogued as rs1340930464; called by muse, varscan2
- MAPK1IP1L | c.609A>G p.A203= | Silent (SNP) | VAF 12/309 reads (4%) | called by muse, mutect2
- MAPRE3 | c.615C>G p.L205= | Silent (SNP) | VAF 16/191 reads (8%) | called by muse, mutect2
- MAST3 | c.1458C>T p.I486= | Silent (SNP) | VAF 25/307 reads (8%) | catalogued as rs1279061919, COSV99446065; called by muse, mutect2
- MSH2 | c.2124C>T p.I708= | Silent (SNP) | VAF 28/426 reads (7%) | called by muse, mutect2
- MYMK | c.417G>A p.E139= | Silent (SNP) | VAF 24/216 reads (11%) | called by muse, mutect2
- NGEF | c.102A>G p.L34= | Silent (SNP) | VAF 29/389 reads (7%) | called by muse, mutect2
- NONO | c.1263G>A p.P421= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as rs141184952; called by muse, mutect2
- NT5E | c.1410C>G p.V470= | Silent (SNP) | VAF 27/367 reads (7%) | catalogued as COSV100004474; called by muse, mutect2
- OR10H5 | c.99G>A p.L33= | Silent (SNP) | VAF 12/242 reads (5%) | catalogued as COSV100454611; called by muse, mutect2
- ORC5 | c.924C>T p.F308= | Silent (SNP) | VAF 6/97 reads (6%) | catalogued as rs965403836; called by muse, mutect2
- PKD1 | c.9363G>A p.E3121= | Silent (SNP) | VAF 57/502 reads (11%) | called by muse, mutect2, varscan2
- PLEC | c.5937C>T p.I1979= (on ENST00000322810 / NM_201380.4; = p.I1869= on NM_000445.5) | Silent (SNP) | VAF 18/436 reads (4%) | catalogued as rs782554733, COSV59674835; ClinVar: likely benign; called by muse, mutect2
- RAB11FIP5 | c.1383G>C p.R461= | Silent (SNP) | VAF 17/404 reads (4%) | called by muse, mutect2
- RTEL1 | c.27G>A p.V9= | Silent (SNP) | VAF 37/279 reads (13%) | called by muse, mutect2, varscan2
- RYR1 | c.3135C>T p.L1045= | Silent (SNP) | VAF 26/302 reads (9%) | catalogued as COSV100617664; called by muse, mutect2
- SCNN1A | c.1698G>A p.V566= | Silent (SNP) | VAF 32/406 reads (8%) | catalogued as rs746962921; called by muse, mutect2
- SEMA5A | c.2700G>T p.S900= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as COSV66786330; called by muse, mutect2
- SLC12A5 | c.825C>G p.V275= (on ENST00000454036 / NM_001134771.2; = p.V252= on NM_020708.5) | Silent (SNP) | VAF 12/444 reads (3%) | called by muse, mutect2
- SLC17A3 | c.639C>T p.L213= | Silent (SNP) | VAF 14/428 reads (3%) | called by muse, mutect2
- SLC26A11 | c.855C>T p.I285= | Silent (SNP) | VAF 7/161 reads (4%) | called by muse, mutect2
- SRPK3 | c.1308C>T p.I436= | Silent (SNP) | VAF 7/117 reads (6%) | catalogued as rs139853635, COSV54207800; called by muse, mutect2
- TERT | c.2178G>A p.T726= | Silent (SNP) | VAF 44/623 reads (7%) | catalogued as rs199422288, COSV57211310; ClinVar: likely benign / benign; called by muse, mutect2
- THSD4 | c.1320C>T p.I440= | Silent (SNP) | VAF 32/435 reads (7%) | called by muse, mutect2
- TLR4 | c.495C>T p.F165= (on ENST00000355622 / NM_138554.5; = p.F125= on NM_003266.4) | Silent (SNP) | VAF 11/178 reads (6%) | catalogued as COSV62922599; called by muse, mutect2
- TMEM26 | c.112C>T p.L38= | Silent (SNP) | VAF 14/258 reads (5%) | called by muse, mutect2
- UPF2 | c.2607C>T p.I869= | Silent (SNP) | VAF 12/86 reads (14%) | called by muse, varscan2
- WDR81 | c.4914G>A p.Q1638= (on ENST00000409644 / NM_001163809.2; = p.Q587= on NM_152348.4) | Silent (SNP) | VAF 47/384 reads (12%) | called by muse, mutect2, varscan2
- WTIP | c.417C>T p.S139= | Silent (SNP) | VAF 15/155 reads (10%) | called by muse, mutect2
- ZDHHC8 | c.1299G>A p.L433= | Silent (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- ZNF404 | c.1308G>A p.E436= | Silent (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- ZNF689 | c.1362G>A p.E454= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV54910243; called by muse, mutect2
- BICD1 | c.213+1131C>G | Intron (SNP) | VAF 5/53 reads (9%) | catalogued as rs760811341; called by mutect2, varscan2
- BRK1 | c.*23G>C | 3'UTR (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- CCDC65 | chr12:48923918 G>A | 3'Flank (SNP) | VAF 14/478 reads (3%) | called by muse, mutect2
- CRB1 | c.4005+115G>C | Intron (SNP) | VAF 6/128 reads (5%) | catalogued as COSV100958030; called by muse, mutect2
- DIABLO | c.-59C>T | 5'UTR (SNP) | VAF 38/617 reads (6%) | catalogued as rs370060703; called by muse, mutect2
- GRAMD1A | chr19:34996161 T>C | 5'Flank (SNP) | VAF 13/339 reads (4%) | called by muse, mutect2
- H3P12 | chr3:109410206 G>C | 5'Flank (SNP) | VAF 13/176 reads (7%) | catalogued as rs1357678862; called by muse, mutect2
- IGFN1 | c.1241+2815G>A | Intron (SNP) | VAF 20/275 reads (7%) | catalogued as rs1209079502; called by muse, mutect2
- MARCHF1 | c.-322-85581G>A | Intron (SNP) | VAF 12/286 reads (4%) | catalogued as COSV72277527; called by muse, mutect2
- MOG | c.730+73G>C | Intron (SNP) | VAF 20/426 reads (5%) | called by muse, mutect2
- MOV10L1 | c.97+299C>T | Intron (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- OR2A13P | n.201C>T | RNA (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- PAF1 | c.293-9C>G | Intron (SNP) | VAF 9/190 reads (5%) | catalogued as rs1228856319; called by muse, mutect2
- PAICS | c.-41C>T | 5'UTR (SNP) | VAF 11/111 reads (10%) | catalogued as rs924488741, COSV99947232; called by muse, varscan2
- PARD3B | c.2630+16G>C | Intron (SNP) | VAF 7/138 reads (5%) | called by muse, mutect2
- POLR3B | c.-26C>T | 5'UTR (SNP) | VAF 19/545 reads (3%) | catalogued as COSV99942921; called by muse, mutect2
- RPGR | c.619+23C>G | Intron (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- SP5 | chr2:170713864 G>C | 5'Flank (SNP) | VAF 8/234 reads (3%) | catalogued as rs1281157930; called by muse, mutect2
- SSR2 | c.*23C>G | 3'UTR (SNP) | VAF 54/299 reads (18%) | called by muse, mutect2, varscan2
- TCEA1 | c.127-3002G>C | Intron (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- ZNF812P | n.709G>A | RNA (SNP) | VAF 6/149 reads (4%) | catalogued as rs1432608593; called by muse, mutect2
